Somatic mutation profile of tumor specimen C3L-05259-01 (aliquot CPT0340860007) from CPTAC case C3L-05259, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 82.7 years (30,224 days).
Specimen C3L-05259-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 95bbd060-cd4b-4735-afb0-4daeb1f5cf06.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-05259-31 (Blood Derived Normal), aliquot CPT0340960002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/82082abc-8316-434d-b15a-44fac7851167

The open-access MAF lists 548 somatic variants for this specimen: 356 protein-altering or splice-affecting, 171 silent, 21 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 318, Silent 171, Nonsense Mutation 23, Intron 15, Splice Region 7, Frame Shift Del 4, RNA 3, Splice Site 2, 5'UTR 2, 3'UTR 1, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EYA4 | c.455T>A p.L152H | Missense Mutation (SNP) | VAF 29/453 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62044745, COSV62052190, COSV62055739; called by muse, mutect2
- EYS | c.4120C>T p.R1374* | Nonsense Mutation (SNP) | VAF 87/502 reads (17%) | catalogued as rs928803207, CM107715, COSV58199378; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 111/470 reads (24%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- RAC1 | c.85C>A p.P29T | Missense Mutation (SNP) | VAF 353/599 reads (59%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.936); catalogued as rs1057519874, COSV61821563, COSV61823187; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RAF1 | c.776C>T p.S259F | Missense Mutation (SNP) | VAF 113/548 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs397516827, CM073300, COSV52574365, COSV52575478; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.5158G>A p.D1720N (on ENST00000272895 / NM_173076.3; = p.D1402N on NM_015657.3) | Missense Mutation (SNP) | VAF 71/333 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.018); catalogued as COSV99792313; called by muse, mutect2, varscan2
- ABCA3 | c.4090G>A p.E1364K | Missense Mutation (SNP) | VAF 99/502 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1413175771; called by muse, mutect2, varscan2
- ABCC2 | c.890A>G p.K297R | Missense Mutation (SNP) | VAF 84/330 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as COSV64970824; called by muse, mutect2, varscan2
- ABCD4 | c.1690C>T p.R564C | Missense Mutation (SNP) | VAF 96/488 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.724); catalogued as rs778089332; called by muse, mutect2, varscan2
- ACTL7B | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 122/568 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV65927161; called by muse, mutect2, varscan2
- ACVR1C | c.953C>A p.A318D | Missense Mutation (SNP) | VAF 48/242 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99694250; called by mutect2, varscan2
- ADAMTS12 | c.3965G>A p.W1322* | Nonsense Mutation (SNP) | VAF 48/337 reads (14%) | catalogued as COSV100710083; called by muse, mutect2, varscan2
- ADAMTS20 | c.4180G>A p.E1394K | Missense Mutation (SNP) | VAF 104/374 reads (28%) | SIFT tolerated (0.82); PolyPhen benign (0.086); catalogued as COSV101166063; called by muse, mutect2, varscan2
- ADGRA1 | c.1243G>A p.G415R | Missense Mutation (SNP) | VAF 134/661 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs759466398; called by muse, mutect2, varscan2
- ADGRB3 | c.2402C>T p.S801L | Missense Mutation (SNP) | VAF 61/387 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.102); catalogued as rs747907463, COSV101000565, COSV65385017; called by muse, mutect2, varscan2
- ADGRL2 | c.4039G>A p.G1347R (on ENST00000370717 / NM_001366005.1; = p.G1291R on NM_012302.4) | Missense Mutation (SNP) | VAF 95/514 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.384); catalogued as rs761678542, COSV99591848; called by muse, varscan2
- AP4B1 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 61/333 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as rs534678582; called by muse, mutect2, varscan2
- AP4E1 | c.3295C>T p.P1099S | Missense Mutation (SNP) | VAF 92/427 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.435); catalogued as COSV55917132; called by muse, mutect2, varscan2
- APBA1 | c.71C>T p.S24L | Missense Mutation (SNP) | VAF 119/624 reads (19%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.062); catalogued as rs1225653625, COSV55233056; called by muse, mutect2, varscan2
- ASTN1 | c.2378G>A p.G793E | Missense Mutation (SNP) | VAF 57/277 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs867077481, COSV99921157, COSV99923086; called by muse, mutect2, varscan2
- ATAD2 | c.3260C>T p.A1087V | Missense Mutation (SNP) | VAF 66/405 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.835); catalogued as rs1330095007, COSV99784970; called by muse, mutect2, varscan2
- ATP6V0A4 | c.1700G>A p.R567K | Missense Mutation (SNP) | VAF 52/283 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.046); catalogued as COSV59480007; called by muse, mutect2, varscan2
- AXIN1 | c.1144C>T p.R382C | Missense Mutation (SNP) | VAF 97/463 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.794); catalogued as rs201609463, COSV51983067; called by muse, mutect2, varscan2
- B3GALT1 | c.104C>T p.S35F | Missense Mutation (SNP) | VAF 100/467 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs1445278259, COSV59909890; called by muse, mutect2, varscan2
- BCLAF1 | c.956C>T p.S319F | Missense Mutation (SNP) | VAF 30/255 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.098); catalogued as rs769117855, COSV62145327; called by muse, mutect2, varscan2
- BFSP1 | c.1964C>T p.S655L | Missense Mutation (SNP) | VAF 64/378 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV100925466; called by muse, mutect2
- BHLHA15 | c.152G>A p.R51K | Missense Mutation (SNP) | VAF 150/762 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1426422499; called by muse, mutect2, varscan2
- BNC2 | c.871C>G p.R291G | Missense Mutation (SNP) | VAF 89/422 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.379); catalogued as COSV101032846, COSV66152072; called by muse, mutect2, varscan2
- BSN | c.1882C>T p.P628S | Missense Mutation (SNP) | VAF 120/586 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs139475033; called by muse, mutect2, varscan2
- CARMIL2 | c.1222C>T p.P408S | Missense Mutation (SNP) | VAF 139/607 reads (23%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.001); catalogued as rs535663690; called by muse, mutect2, varscan2
- CCDC134 | c.422G>T p.R141L | Missense Mutation (SNP) | VAF 84/497 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as rs1441163914; called by muse, mutect2, varscan2
- CCDC178 | c.1501G>A p.E501K | Missense Mutation (SNP) | VAF 78/431 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.045); catalogued as COSV55760974; called by muse, mutect2, varscan2
- CCL20 | c.115C>T p.R39C | Missense Mutation (SNP) | VAF 69/343 reads (20%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.744); catalogued as rs781267345, COSV62591181; called by muse, mutect2, varscan2
- CD58 | c.320C>T p.S107L | Missense Mutation (SNP) | VAF 56/353 reads (16%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.977); catalogued as rs1266661778, COSV101043992, COSV65665227, COSV65665606; called by muse, mutect2, varscan2
- CDH23 | c.6320G>A p.R2107Q | Missense Mutation (SNP) | VAF 75/364 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs780094972, COSV56460135; called by muse, mutect2, varscan2
- CIC | c.3022C>T p.Q1008* | Nonsense Mutation (SNP) | VAF 76/402 reads (19%) | catalogued as COSV50653831; called by muse, mutect2, varscan2
- CLSTN3 | c.2011C>T p.Q671* | Nonsense Mutation (SNP) | VAF 107/498 reads (21%) | catalogued as COSV99867879; called by muse, mutect2, varscan2
- CNDP1 | c.467G>A p.G156E | Missense Mutation (SNP) | VAF 58/254 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs1388658213; called by muse, varscan2
- CNGA1 | c.438G>A p.E146= | Splice Region (SNP) | VAF 41/295 reads (14%) | catalogued as COSV62053671; called by muse, mutect2, varscan2
- CNTNAP5 | c.1612G>A p.D538N | Missense Mutation (SNP) | VAF 62/311 reads (20%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.973); catalogued as COSV101443138; called by muse, mutect2, varscan2
- COL11A1 | c.3928C>T p.P1310S | Missense Mutation (SNP) | VAF 68/382 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.194); catalogued as COSV62199480; called by muse, mutect2, varscan2
- COL11A1 | c.329G>A p.G110E | Missense Mutation (SNP) | VAF 55/330 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV62188559; called by muse, mutect2, varscan2
- COL12A1 | c.7439T>G p.V2480G | Missense Mutation (SNP) | VAF 77/481 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59407155; called by muse, mutect2, varscan2
- COL12A1 | c.3929G>A p.G1310E | Missense Mutation (SNP) | VAF 103/526 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59402509; called by muse, mutect2, varscan2
- CPAMD8 | c.1702C>T p.R568C (on ENST00000651564; = p.R521C on NM_015692.5) | Missense Mutation (SNP) | VAF 83/420 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.067); catalogued as rs762584662, COSV52230795; called by muse, mutect2
- CSMD3 | c.7423C>T p.P2475S (on ENST00000297405 / NM_001363185.1; = p.P2371S on NM_052900.3) | Missense Mutation (SNP) | VAF 67/372 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52319964, COSV52337154; called by muse, mutect2, varscan2
- CYP3A4 | c.778C>T p.R260C | Missense Mutation (SNP) | VAF 32/204 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.291); catalogued as rs750301316, COSV60502822; called by muse, mutect2, varscan2
- DCC | c.3310G>A p.V1104I | Missense Mutation (SNP) | VAF 94/483 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.412); catalogued as COSV71441562; called by muse, mutect2, varscan2
- DISP3 | c.1910G>A p.R637Q | Missense Mutation (SNP) | VAF 97/495 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as rs756856438, COSV53828906; called by muse, mutect2, varscan2
- DLEC1 | c.1859G>A p.R620Q | Missense Mutation (SNP) | VAF 107/570 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.706); catalogued as rs747150027, COSV57296894; called by muse, mutect2, varscan2
- DMBT1 | c.6319C>T p.R2107C (on ENST00000338354 / NM_001377530.1; = p.R1350C on NM_004406.3) | Missense Mutation (SNP) | VAF 54/337 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.972); catalogued as rs747972203, COSV57544508; called by muse, mutect2, varscan2
- DNAH10 | c.2384C>T p.S795F (on ENST00000409039; = p.S734F on NM_207437.3) | Missense Mutation (SNP) | VAF 71/404 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs201967312; called by muse, mutect2, varscan2
- DNAH11 | c.6202C>T p.R2068C | Missense Mutation (SNP) | VAF 352/635 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.246); catalogued as rs745332741, COSV60940114; called by muse, mutect2, varscan2
- DNAH12 | c.1312C>T p.H438Y | Missense Mutation (SNP) | VAF 58/298 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100244462; called by muse, mutect2, varscan2
- DNAH3 | c.8971C>T p.R2991C | Missense Mutation (SNP) | VAF 126/575 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.863); catalogued as rs777070451, COSV54544657; called by muse, mutect2, varscan2
- DNAH3 | c.8457C>T p.S2819= | Splice Region (SNP) | VAF 49/274 reads (18%) | catalogued as rs754426138, COSV54509182; called by muse, mutect2, varscan2
- DNAH3 | c.3910G>A p.E1304K | Missense Mutation (SNP) | VAF 75/341 reads (22%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as rs1157642968; called by muse, mutect2, varscan2
- DNAH3 | c.3562G>A p.E1188K | Missense Mutation (SNP) | VAF 20/572 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs933235238, COSV99771298; called by muse, mutect2
- DNAJB11 | c.763G>A p.G255R | Missense Mutation (SNP) | VAF 65/311 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1230940195; called by muse, mutect2, varscan2
- DNAJC16 | c.74C>T p.A25V | Missense Mutation (SNP) | VAF 74/437 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as rs888133157; called by muse, mutect2, varscan2
- DNMBP | c.3718G>A p.E1240K | Missense Mutation (SNP) | VAF 91/481 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs773799298; called by muse, mutect2, varscan2
- DRD5 | c.1120G>A p.G374R | Missense Mutation (SNP) | VAF 104/521 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as rs747270210; called by muse, mutect2, varscan2
- DSP | c.4373G>A p.R1458Q | Missense Mutation (SNP) | VAF 101/565 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.111); catalogued as rs370063434, COSV65791413; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EGFLAM | c.2845G>A p.G949S (on ENST00000354891 / NM_001205301.2; = p.G941S on NM_152403.4) | Missense Mutation (SNP) | VAF 60/369 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs749437026; called by muse, mutect2, varscan2
- EIF4G1 | c.943C>T p.P315S (on ENST00000346169 / NM_198241.3; = p.P119S on NM_004953.5) | Missense Mutation (SNP) | VAF 81/472 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV100072243; called by muse, mutect2, varscan2
- EPHA1 | c.356A>G p.K119R | Missense Mutation (SNP) | VAF 132/610 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs961153147; called by muse, mutect2, varscan2
- EYS | c.2259C>T p.L753= | Splice Region (SNP) | VAF 40/237 reads (17%) | catalogued as rs781359405, COSV65564032; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAM170A | c.984G>A p.R328= | Splice Region (SNP) | VAF 79/336 reads (24%) | catalogued as COSV100088633, COSV58924153; called by muse, mutect2, varscan2
- FAT4 | c.14164G>A p.E4722K | Missense Mutation (SNP) | VAF 80/453 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as COSV58672832, COSV58712191; called by muse, mutect2, varscan2
- FGF14 | c.381G>A p.M127I | Missense Mutation (SNP) | VAF 55/291 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as rs757596950, COSV65938028; called by muse, mutect2, varscan2
- FLT3 | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 69/321 reads (21%) | SIFT tolerated (0.83); PolyPhen benign (0.001); catalogued as COSV54070194; called by muse, mutect2, varscan2
- G6PC | c.856G>A p.G286R | Missense Mutation (SNP) | VAF 94/525 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as rs534670926, COSV53830677; called by muse, mutect2, varscan2
- GHR | c.48T>G p.S16R | Missense Mutation (SNP) | VAF 38/403 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.296); catalogued as rs1174610023; called by muse, mutect2
- GOLGA6L7 | c.1171G>A p.G391R | Missense Mutation (SNP) | VAF 128/759 reads (17%) | SIFT tolerated (1); catalogued as rs879072018; called by muse, mutect2, varscan2
- GPR149 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 78/397 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.146); catalogued as rs757829466; called by muse, mutect2, varscan2
- GPR22 | c.137G>A p.G46E | Missense Mutation (SNP) | VAF 102/454 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.478); catalogued as rs1419439157; called by muse, mutect2, varscan2
- GRM3 | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 96/496 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.1); catalogued as rs539317443, COSV64468514, COSV64477690; called by muse, mutect2, varscan2
- GRXCR1 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 87/536 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.534); catalogued as COSV67669790; called by muse, mutect2, varscan2
- GYS1 | c.1444C>T p.L482F | Missense Mutation (SNP) | VAF 61/314 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV99620950; called by muse, mutect2, varscan2
- H2BC12 | c.378G>C p.K126N | Missense Mutation (SNP) | VAF 67/411 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as rs765695435, COSV100804719, COSV63616594; called by muse, mutect2, varscan2
- HGFAC | c.1960C>T p.P654S | Missense Mutation (SNP) | VAF 80/373 reads (21%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.055); catalogued as COSV66977103; called by muse, mutect2, varscan2
- HR | c.2708C>T p.P903L | Missense Mutation (SNP) | VAF 115/640 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs1015333064; called by muse, mutect2, varscan2
- HYAL2 | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 108/631 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as rs782642246; called by muse, mutect2, varscan2
- HYDIN | c.3667C>T p.P1223S | Missense Mutation (SNP) | VAF 78/410 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.168); catalogued as rs754850632; called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.300G>A p.M100I | Missense Mutation (SNP) | VAF 68/893 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.295); catalogued as rs370560002; called by muse, mutect2
- IQSEC3 | c.3173G>A p.R1058K | Missense Mutation (SNP) | VAF 116/648 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs767354958; called by muse, mutect2, varscan2
- KCNJ15 | c.280G>A p.D94N | Missense Mutation (SNP) | VAF 105/515 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs147233830; called by muse, mutect2, varscan2
- KCNK13 | c.532G>A p.D178N | Missense Mutation (SNP) | VAF 129/633 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs1364274622, COSV56410812; called by muse, mutect2, varscan2
- KIAA1109 | c.8837C>T p.P2946L | Missense Mutation (SNP) | VAF 78/336 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV52685390; called by muse, mutect2, varscan2
- LAMA2 | c.1589C>T p.S530F | Missense Mutation (SNP) | VAF 59/281 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.58); catalogued as rs760095810, COSV101370354; called by muse, mutect2, varscan2
- LMX1B | c.722C>T p.S241L | Missense Mutation (SNP) | VAF 88/393 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as CM992924, COSV100827317; called by muse, mutect2, varscan2
- LRRC37A3 | c.4823G>A p.R1608Q | Missense Mutation (SNP) | VAF 61/396 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs768967057, COSV58534675; called by muse, mutect2, varscan2
- MACF1 | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 109/527 reads (21%) | catalogued as COSV58369638; called by muse, mutect2, varscan2
- MAGEB6 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 135/356 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.177); catalogued as COSV66872786; called by muse, varscan2
- MCM10 | c.145G>A p.D49N | Missense Mutation (SNP) | VAF 108/487 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs761499773; called by muse, mutect2, varscan2
- MEPE | c.166C>T p.Q56* | Nonsense Mutation (SNP) | VAF 48/311 reads (15%) | catalogued as COSV63074636; called by muse, mutect2, varscan2
- MGAM | c.5260G>A p.D1754N | Missense Mutation (SNP) | VAF 87/513 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs779200546, COSV72074236; called by muse, mutect2, varscan2
- MS4A18 | c.82C>T p.P28S | Missense Mutation (SNP) | VAF 96/459 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs1209222912; called by muse, mutect2, varscan2
- MUC16 | c.43228G>A p.E14410K | Missense Mutation (SNP) | VAF 64/463 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV66694294; called by muse, mutect2, varscan2
- MUC16 | c.31661C>T p.P10554L | Missense Mutation (SNP) | VAF 92/509 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.367); catalogued as rs1451903392; called by muse, mutect2, varscan2
- MUC7 | c.752C>T p.S251F | Missense Mutation (SNP) | VAF 132/716 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV59217196; called by muse, varscan2
- MYH11 | c.5557G>A p.E1853K | Missense Mutation (SNP) | VAF 111/544 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.247); catalogued as COSV55543546; called by muse, mutect2, varscan2
- MYH8 | c.1144G>A p.E382K | Missense Mutation (SNP) | VAF 85/280 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.438); catalogued as COSV67965711; called by muse, mutect2, varscan2
- MYLK3 | c.596G>A p.G199E | Missense Mutation (SNP) | VAF 104/494 reads (21%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.87); catalogued as rs1271461148, COSV67364362; called by muse, mutect2, varscan2
- MYO5B | c.4513C>T p.L1505F | Missense Mutation (SNP) | VAF 86/472 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs751931284; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYOF | c.843G>A p.K281= | Splice Region (SNP) | VAF 110/466 reads (24%) | catalogued as rs752635845, COSV63701226; called by muse, mutect2, varscan2
- NBEA | c.7024G>A p.D2342N | Missense Mutation (SNP) | VAF 41/261 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV59805112, COSV59824980; called by muse, mutect2, varscan2
- NEO1 | c.3626A>T p.H1209L | Missense Mutation (SNP) | VAF 58/417 reads (14%) | SIFT tolerated (1); PolyPhen possibly damaging (0.665); catalogued as COSV99981061; called by muse, mutect2
- NLRP5 | c.2209C>T p.R737W | Missense Mutation (SNP) | VAF 78/503 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs537471101, COSV66762321; called by muse, mutect2, varscan2
- NPC1L1 | c.1205G>A p.G402D | Missense Mutation (SNP) | VAF 86/540 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.125); catalogued as rs1258284957, COSV56924244; called by muse, mutect2, varscan2
- NRXN3 | c.2038G>A p.E680K (on ENST00000335750 / NM_001330195.2; = p.E307K on NM_004796.6) | Missense Mutation (SNP) | VAF 60/340 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV59754688; called by muse, mutect2, varscan2
- OR4D11 | c.882G>A p.M294I | Missense Mutation (SNP) | VAF 71/358 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as rs267603041, COSV100506645, COSV57586488; called by muse, mutect2, varscan2
- OR5AC2 | c.187T>G p.L63V | Missense Mutation (SNP) | VAF 56/510 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.066); catalogued as COSV62279139; called by muse, mutect2, varscan2
- OR5H14 | c.920G>A p.R307K | Missense Mutation (SNP) | VAF 30/213 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs541342101, COSV71193554, COSV71194506; called by muse, mutect2, varscan2
- PAPPA | c.2350G>A p.E784K | Missense Mutation (SNP) | VAF 116/582 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as rs192348737, COSV100073212, COSV60286024; called by muse, mutect2, varscan2
- PCDHA2 | c.1295C>T p.S432L | Missense Mutation (SNP) | VAF 178/710 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.068); catalogued as rs782027744, COSV65366259; called by muse, mutect2, varscan2
- PCDHA8 | c.1915G>A p.E639K | Missense Mutation (SNP) | VAF 130/652 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.506); catalogued as COSV65325085; called by muse, mutect2, varscan2
- PCLO | c.12397C>T p.R4133C | Missense Mutation (SNP) | VAF 111/488 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs372497499; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCLO | c.500C>T p.S167F | Missense Mutation (SNP) | VAF 88/372 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as rs372528729; called by muse, mutect2, varscan2
- PCSK5 | c.2756C>T p.S919L | Missense Mutation (SNP) | VAF 70/370 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs762281568, COSV70449275; called by muse, mutect2, varscan2
- PDE1A | c.1361C>T p.S454F | Missense Mutation (SNP) | VAF 70/336 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as rs202096938, COSV59536038; called by muse, mutect2, varscan2
- PDE1C | c.1645G>A p.E549K | Missense Mutation (SNP) | VAF 95/566 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs868315274, COSV58507904; called by muse, mutect2, varscan2
- PHACTR3 | c.1141G>A p.D381N | Missense Mutation (SNP) | VAF 50/293 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV63026684; called by muse, mutect2, varscan2
- PHOX2B | c.32C>T p.S11F | Missense Mutation (SNP) | VAF 51/387 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.092); catalogued as COSV56929147; called by muse, mutect2, varscan2
- PIEZO1 | c.6989C>T p.P2330L | Missense Mutation (SNP) | VAF 137/530 reads (26%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.635); catalogued as rs1479059774; called by muse, mutect2, varscan2
- PKD1L2 | c.1972C>T p.P658S | Missense Mutation (SNP) | VAF 54/326 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.57); catalogued as COSV100216485; called by muse, mutect2, varscan2
- PLCL1 | c.1465C>T p.L489F | Missense Mutation (SNP) | VAF 109/526 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV70843182, COSV70851373; called by muse, mutect2, varscan2
- PLD1 | c.643C>T p.H215Y | Missense Mutation (SNP) | VAF 87/445 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs1338897869; called by muse, mutect2, varscan2
- PNMA6E | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 71/203 reads (35%) | SIFT deleterious (0); catalogued as COSV70165341; called by muse, mutect2, varscan2
- PNPLA6 | c.836C>T p.P279L (on ENST00000414982 / NM_001166111.2; = p.P231L on NM_006702.5) | Missense Mutation (SNP) | VAF 62/442 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.647); catalogued as rs771167270; called by muse, mutect2, varscan2
- POFUT1 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 118/524 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.245); catalogued as COSV65337042; called by muse, mutect2, varscan2
- PPP1R7 | c.337A>T p.I113F | Missense Mutation (SNP) | VAF 40/255 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs988496635; called by muse, mutect2, varscan2
- PRAMEF20 | c.109C>T p.P37S | Missense Mutation (SNP) | VAF 137/723 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763463965; called by muse, mutect2, varscan2
- PRB2 | c.809G>A p.G270E | Missense Mutation (SNP) | VAF 105/813 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.193); catalogued as COSV101231364; called by muse, mutect2, varscan2
- RASGRF1 | c.481C>T p.R161W | Missense Mutation (SNP) | VAF 94/507 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753280280, COSV69179038; called by muse, mutect2, varscan2
- RCOR3 | c.1184C>T p.P395L | Missense Mutation (SNP) | VAF 77/544 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.223); catalogued as COSV65364617; called by muse, mutect2, varscan2
- RNASE12 | c.371C>T p.S124F | Missense Mutation (SNP) | VAF 124/568 reads (22%) | SIFT tolerated (0.81); PolyPhen benign (0.007); catalogued as rs201559377, COSV60088418; called by muse, mutect2, varscan2
- RNF217 | c.1523G>A p.G508E (on ENST00000521654 / NM_001286398.2; = p.G216E on NM_152553.5) | Missense Mutation (SNP) | VAF 43/311 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as COSV51575101; called by muse, mutect2, varscan2
- RPL9 | c.114C>A p.F38L | Missense Mutation (SNP) | VAF 56/258 reads (22%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.651); catalogued as rs147466054; called by muse, mutect2, varscan2
- RPTN | c.1022C>T p.S341F | Missense Mutation (SNP) | VAF 127/698 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV60166549; called by muse, mutect2, varscan2
- RSPH1 | c.694G>A p.D232N | Missense Mutation (SNP) | VAF 126/528 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.112); catalogued as COSV99370629; called by muse, mutect2, varscan2
- RSPH6A | c.1895C>T p.A632V | Missense Mutation (SNP) | VAF 62/400 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs45486500; called by muse, mutect2, varscan2
- RUNX1T1 | c.748G>A p.E250K (on ENST00000265814 / NM_001198628.1; = p.E223K on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/255 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.217); catalogued as COSV56136217; called by muse, mutect2, varscan2
- SAMD9L | c.3350C>T p.S1117F | Missense Mutation (SNP) | VAF 70/356 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59079287; called by muse, mutect2, varscan2
- SCN10A | c.5833G>A p.E1945K | Missense Mutation (SNP) | VAF 84/369 reads (23%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs760570118, COSV71860380, COSV71861055; called by muse, mutect2, varscan2
- SCN5A | c.2713G>A p.D905N | Missense Mutation (SNP) | VAF 94/433 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV61142954; called by muse, mutect2, varscan2
- SLC2A1 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 99/475 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM044066; called by muse, mutect2, varscan2
- SLC30A2 | c.437C>T p.T146I | Missense Mutation (SNP) | VAF 73/361 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1436063314; called by muse, mutect2, varscan2
- SLC5A8 | c.1160G>A p.G387E | Missense Mutation (SNP) | VAF 73/339 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV73310331, COSV73310495; called by muse, mutect2, varscan2
- SLC7A9 | c.998G>T p.R333L | Missense Mutation (SNP) | VAF 58/338 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as CM061205, COSV99195208; called by muse, mutect2, varscan2
- SLC8A2 | c.413C>T p.S138F | Missense Mutation (SNP) | VAF 74/526 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52642548; called by muse, mutect2, varscan2
- SNAP25 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 76/434 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs867509488, COSV54772730, COSV54774563; called by muse, mutect2, varscan2
- SORCS3 | c.1226G>A p.G409E | Missense Mutation (SNP) | VAF 71/357 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1234740080; called by muse, mutect2, varscan2
- SORCS3 | c.3148C>T p.P1050S | Missense Mutation (SNP) | VAF 78/345 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1322941069, COSV63803440; called by muse, mutect2, varscan2
- SPEF2 | c.4177G>A p.E1393K | Missense Mutation (SNP) | VAF 65/327 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as COSV57430613; called by muse, mutect2, varscan2
- SPEN | c.5053C>T p.P1685S | Missense Mutation (SNP) | VAF 96/525 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1425078446; called by muse, mutect2, varscan2
- STAB2 | c.1919C>T p.A640V | Missense Mutation (SNP) | VAF 98/538 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.289); catalogued as rs761905917, COSV66343991; called by muse, mutect2, varscan2
- STAB2 | c.2249G>A p.G750E | Missense Mutation (SNP) | VAF 62/320 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as rs267603273, COSV66336543; called by muse, mutect2, varscan2
- STOX2 | c.1847C>T p.P616L | Missense Mutation (SNP) | VAF 110/549 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.521); catalogued as rs747170021; called by muse, mutect2, varscan2
- SYNE1 | c.13369C>T p.Q4457* (on ENST00000367255 / NM_182961.4; = p.Q4386* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 93/504 reads (18%) | catalogued as COSV99568864; called by muse, mutect2, varscan2
- TACC2 | c.8420C>T p.S2807F (on ENST00000334433; = p.S885F on NM_006997.4) | Missense Mutation (SNP) | VAF 80/416 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1226848799; called by muse, mutect2, varscan2
- TBC1D31 | c.572C>T p.S191F | Missense Mutation (SNP) | VAF 76/365 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV54867984; called by muse, mutect2, varscan2
- TEC | c.65C>T p.S22L | Missense Mutation (SNP) | VAF 106/485 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs772497479, COSV67404948; called by muse, mutect2, varscan2
- TFEB | c.344C>T p.P115L | Missense Mutation (SNP) | VAF 118/648 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as rs746642722, COSV100026383, COSV57823668; called by muse, mutect2, varscan2
- TG | c.8002C>T p.P2668S | Missense Mutation (SNP) | VAF 83/372 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV55091890; called by muse, mutect2, varscan2
- TLL2 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 55/358 reads (15%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.633); catalogued as COSV63572469; called by muse, mutect2, varscan2
- TLR6 | c.1661G>A p.G554D | Missense Mutation (SNP) | VAF 114/536 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs757237670; called by muse, mutect2, varscan2
- TNXB | c.2362G>A p.E788K | Missense Mutation (SNP) | VAF 53/353 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.108); catalogued as rs761344131; called by muse, mutect2, varscan2
- TOP3B | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 84/465 reads (18%) | SIFT tolerated (0.92); PolyPhen benign (0.001); catalogued as rs547739259; called by muse, mutect2, varscan2
- TRIM2 | c.1685C>T p.S562F (on ENST00000437508; = p.S589F on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/268 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.125); catalogued as rs921922842, COSV58632972; called by muse, mutect2, varscan2
- TRIM40 | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 365/1032 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.265); catalogued as COSV57157541; called by muse, mutect2, varscan2
- TTC9 | c.526C>T p.H176Y | Missense Mutation (SNP) | VAF 91/524 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56448494; called by muse, mutect2, varscan2
- TTN | c.47875G>A p.E15959K (on ENST00000591111; = p.E8535K on NM_003319.4) | Missense Mutation (SNP) | VAF 90/491 reads (18%) | PolyPhen benign (0.359); catalogued as rs745629273, COSV59970551; called by muse, mutect2, varscan2
- USP21 | c.1415C>T p.S472F | Missense Mutation (SNP) | VAF 61/352 reads (17%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.992); catalogued as COSV57088638; called by muse, mutect2, varscan2
- USP32 | c.986C>T p.T329I | Missense Mutation (SNP) | VAF 45/352 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.554); catalogued as COSV56268065; called by muse, mutect2, varscan2
- VCAM1 | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 70/429 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1181312195; called by muse, mutect2, varscan2
- VEGFC | c.1118G>A p.G373E | Missense Mutation (SNP) | VAF 92/417 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54595276; called by muse, mutect2, varscan2
- VEZF1 | c.863C>T p.S288L | Missense Mutation (SNP) | VAF 103/465 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.514); catalogued as COSV51967807, COSV51969785; called by muse, mutect2, varscan2
- VNN1 | c.865C>T p.H289Y | Missense Mutation (SNP) | VAF 64/380 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.028); catalogued as rs955598054, COSV63389481; called by muse, mutect2, varscan2
- WDR33 | c.1453G>T p.D485Y | Missense Mutation (SNP) | VAF 105/529 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV100460570; called by muse, mutect2, varscan2
- WDR49 | c.1040C>T p.P347L (on ENST00000308378 / NM_001366158.1; = p.P688L on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 72/446 reads (16%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs983630830; called by muse, mutect2, varscan2
- WDR87 | c.923C>T p.S308F | Missense Mutation (SNP) | VAF 62/425 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.601); catalogued as rs1371041062, COSV58192838; called by muse, mutect2, varscan2
- XAGE5 | c.301G>A p.G101R | Missense Mutation (SNP) | VAF 57/139 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs782007681; called by muse, mutect2, varscan2
- ZBBX | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 72/338 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as COSV56789433; called by muse, mutect2, varscan2
- ZC3H12B | c.1730G>A p.R577Q | Missense Mutation (SNP) | VAF 130/337 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0.368); catalogued as rs776451042, COSV100162205; called by muse, mutect2, varscan2
- ZFYVE27 | c.184C>T p.R62* | Nonsense Mutation (SNP) | VAF 68/327 reads (21%) | catalogued as rs1340020391; called by muse, mutect2, varscan2
- ZNF366 | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 143/616 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.017); catalogued as rs370140451; called by muse, mutect2, varscan2
- ZNF534 | c.913C>T p.H305Y (on ENST00000332323 / NM_001143939.3; = p.H292Y on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 86/466 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); catalogued as rs267605633, COSV56514865; called by muse, mutect2, varscan2
- ZNF727 | c.832C>T p.H278Y | Missense Mutation (SNP) | VAF 84/538 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV70702492; called by muse, mutect2, varscan2
- ABCC9 | c.2845C>T p.Q949* | Nonsense Mutation (SNP) | VAF 52/299 reads (17%) | called by muse, mutect2, varscan2
- AC008397.2 | c.331G>A p.V111I | Missense Mutation (SNP) | VAF 124/594 reads (21%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ACTR3B | c.94C>T p.P32S | Missense Mutation (SNP) | VAF 31/430 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ACVRL1 | c.565G>A p.G189R | Missense Mutation (SNP) | VAF 79/385 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTS12 | c.4388C>G p.S1463C | Missense Mutation (SNP) | VAF 109/448 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- ADAMTSL2 | c.913C>T p.P305S | Missense Mutation (SNP) | VAF 54/360 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ADCYAP1R1 | c.1176G>A p.Q392= | Splice Region (SNP) | VAF 59/321 reads (18%) | called by muse, mutect2, varscan2
- ADK | c.907G>T p.D303Y (on ENST00000286621; = p.D286Y on NM_001123.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 79/350 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- AFAP1L2 | c.2092G>A p.E698K | Missense Mutation (SNP) | VAF 66/395 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- ALPP | c.1504G>A p.A502T | Missense Mutation (SNP) | VAF 144/780 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, varscan2
- ARHGAP6 | c.1799C>T p.A600V | Missense Mutation (SNP) | VAF 79/187 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- ASXL3 | c.3268C>T p.P1090S | Missense Mutation (SNP) | VAF 100/520 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ATAD2B | c.1888C>T p.P630S | Missense Mutation (SNP) | VAF 87/454 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATP10A | c.2163A>C p.Q721H | Missense Mutation (SNP) | VAF 58/565 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- ATP12A | c.629G>A p.G210E | Missense Mutation (SNP) | VAF 111/571 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATP8B4 | c.3050G>A p.W1017* | Nonsense Mutation (SNP) | VAF 70/368 reads (19%) | called by muse, mutect2, varscan2
- B3GNT5 | c.719C>T p.S240F | Missense Mutation (SNP) | VAF 85/518 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- BAZ2A | c.3911C>G p.P1304R | Missense Mutation (SNP) | VAF 123/584 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- BCL11B | c.1238C>T p.P413L (on ENST00000357195 / NM_001282237.2; = p.P342L on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 110/648 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- BMP5 | c.658C>T p.Q220* | Nonsense Mutation (SNP) | VAF 51/291 reads (18%) | called by muse, mutect2, varscan2
- CA10 | c.533G>A p.G178E | Missense Mutation (SNP) | VAF 79/334 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CABP7 | c.508G>C p.V170L | Missense Mutation (SNP) | VAF 75/360 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CACNA1G | c.6839A>G p.Q2280R | Missense Mutation (SNP) | VAF 144/777 reads (19%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.297); called by muse, mutect2
- CACNA1G | c.6841C>A p.P2281T | Missense Mutation (SNP) | VAF 146/782 reads (19%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); called by muse, mutect2
- CADM3 | c.203A>T p.Q68L (on ENST00000368125 / NM_001127173.3; = p.Q102L on NM_021189.5) | Missense Mutation (SNP) | VAF 67/391 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- CADPS2 | c.1075T>C p.S359P | Missense Mutation (SNP) | VAF 16/407 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.723); called by muse, mutect2
- CAMK4 | c.331C>T p.P111S | Missense Mutation (SNP) | VAF 74/299 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- CATSPERB | c.1174G>A p.E392K | Missense Mutation (SNP) | VAF 87/435 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC196 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 74/357 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.699); called by muse, mutect2, varscan2
- CCDC83 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 47/311 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- CCT8L2 | c.1508G>A p.G503E | Missense Mutation (SNP) | VAF 85/487 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- CDH22 | c.2335G>A p.D779N | Missense Mutation (SNP) | VAF 138/684 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- CFAP44 | c.5417G>A p.R1806K | Missense Mutation (SNP) | VAF 75/321 reads (23%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CFAP46 | c.2992G>A p.E998K | Missense Mutation (SNP) | VAF 60/386 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.638); called by muse, mutect2, varscan2
- CGB5 | c.389G>A p.C130Y | Missense Mutation (SNP) | VAF 55/806 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- CPHXL | c.1040G>A p.W347* | Nonsense Mutation (SNP) | VAF 83/433 reads (19%) | called by muse, mutect2, varscan2
- CRTC1 | c.557C>T p.P186L | Missense Mutation (SNP) | VAF 79/442 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CSPG5 | c.1480C>T p.P494S | Missense Mutation (SNP) | VAF 106/581 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.481); called by muse, mutect2, varscan2
- CUX2 | c.1519T>C p.F507L | Missense Mutation (SNP) | VAF 152/671 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- CYP2C18 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 93/445 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- DACH1 | c.1558C>T p.P520S (on ENST00000619232 / NM_001366712.1; = p.P468S on NM_080759.6) | Missense Mutation (SNP) | VAF 116/483 reads (24%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DDX43 | c.319C>T p.Q107* | Nonsense Mutation (SNP) | VAF 56/246 reads (23%) | called by muse, mutect2, varscan2
- DIRAS1 | c.260C>T p.S87F | Missense Mutation (SNP) | VAF 90/593 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH12 | c.641T>A p.L214* | Nonsense Mutation (SNP) | VAF 89/401 reads (22%) | called by muse, mutect2, varscan2
- DNAH17 | c.5605T>A p.Y1869N | Missense Mutation (SNP) | VAF 97/439 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DNAH5 | c.8347C>T p.P2783S | Missense Mutation (SNP) | VAF 87/477 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- DNAH5 | c.5458G>A p.E1820K | Missense Mutation (SNP) | VAF 82/367 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- DNM1 | c.677C>T p.P226L | Missense Mutation (SNP) | VAF 103/450 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DRD1 | c.925G>A p.D309N | Missense Mutation (SNP) | VAF 131/592 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EIF4G3 | c.262C>T p.P88S | Missense Mutation (SNP) | VAF 48/232 reads (21%) | SIFT deleterious, low confidence (0.02); called by muse, mutect2, varscan2
- ELF4 | c.350C>T p.S117F | Missense Mutation (SNP) | VAF 117/255 reads (46%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- ERN1 | c.1546C>T p.P516S | Missense Mutation (SNP) | VAF 143/683 reads (21%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM163A | c.220G>A p.G74S | Missense Mutation (SNP) | VAF 142/730 reads (19%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- FAM234B | c.950C>T p.P317L | Missense Mutation (SNP) | VAF 105/582 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM83B | c.2615C>A p.P872Q | Missense Mutation (SNP) | VAF 85/513 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- FAT4 | c.59C>T p.S20L | Missense Mutation (SNP) | VAF 98/453 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- FLRT2 | c.14C>T p.T5I | Missense Mutation (SNP) | VAF 74/390 reads (19%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- FREM1 | c.1453C>T p.H485Y | Missense Mutation (SNP) | VAF 78/383 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- FRMD4B | c.674G>A p.R225K | Missense Mutation (SNP) | VAF 80/357 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- FUT7 | c.130C>T p.Q44* | Nonsense Mutation (SNP) | VAF 132/652 reads (20%) | called by muse, mutect2, varscan2
- GOLGA6L7 | c.1172G>A p.G391E | Missense Mutation (SNP) | VAF 131/755 reads (17%) | SIFT tolerated (0.32); called by muse, mutect2, varscan2
- GSTM5 | c.17G>A p.G6E | Missense Mutation (SNP) | VAF 55/349 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GUCY1A2 | c.1588T>G p.F530V | Missense Mutation (SNP) | VAF 55/499 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- H3-4 | c.307G>A p.G103R | Missense Mutation (SNP) | VAF 93/537 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- HELZ2 | c.1946C>T p.S649F (on ENST00000467148 / NM_001037335.2; = p.S80F on NM_033405.3) | Missense Mutation (SNP) | VAF 152/651 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- HEYL | c.480G>A p.M160I | Missense Mutation (SNP) | VAF 142/700 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- HMGB4 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 100/438 reads (23%) | SIFT tolerated (1); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- HS3ST1 | c.440G>A p.R147Q | Missense Mutation (SNP) | VAF 123/627 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HSP90AA1 | c.2143G>A p.E715K | Missense Mutation (SNP) | VAF 109/535 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- HYDIN | c.2557G>A p.E853K | Missense Mutation (SNP) | VAF 36/239 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- IGHV1-45 | c.17G>A p.R6K | Missense Mutation (SNP) | VAF 40/225 reads (18%) | SIFT tolerated (0.57); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- IL1RL2 | c.146C>T p.S49F | Missense Mutation (SNP) | VAF 65/374 reads (17%) | SIFT tolerated (0.73); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- ITM2A | c.493C>T p.L165F | Missense Mutation (SNP) | VAF 101/258 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- JADE3 | c.791C>T p.A264V | Missense Mutation (SNP) | VAF 136/325 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIF21B | c.4399C>T p.Q1467* (on ENST00000422435 / NM_001252100.2; = p.Q1454* on NM_017596.4) | Nonsense Mutation (SNP) | VAF 59/383 reads (15%) | called by muse, mutect2, varscan2
- KLHDC8A | c.616C>T p.P206S | Missense Mutation (SNP) | VAF 98/533 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KLRG2 | c.891G>A p.W297* | Nonsense Mutation (SNP) | VAF 75/434 reads (17%) | called by muse, mutect2, varscan2
- KRT35 | c.1180A>T p.I394F | Missense Mutation (SNP) | VAF 107/620 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KRTAP5-3 | c.306del p.S103Pfs*163 | Frame Shift Del (DEL) | VAF 58/365 reads (16%) | called by pindel, varscan2
- LAMC3 | c.353_356dup p.I120Qfs*11 | Frame Shift Ins (INS) | VAF 67/338 reads (20%) | called by mutect2, pindel, varscan2
- LAMC3 | c.1643G>A p.G548E | Missense Mutation (SNP) | VAF 90/406 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LRP1 | c.10294C>T p.R3432C | Missense Mutation (SNP) | VAF 67/368 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRRC42 | c.542C>T p.S181F | Missense Mutation (SNP) | VAF 88/373 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- MAP3K7 | c.54G>A p.M18I | Missense Mutation (SNP) | VAF 48/438 reads (11%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.38); called by muse, varscan2
- MBD3L1 | c.127A>G p.T43A | Missense Mutation (SNP) | VAF 104/444 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- MET | c.2849G>A p.G950E | Missense Mutation (SNP) | VAF 66/350 reads (19%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- MICAL2 | c.5479G>A p.G1827S | Missense Mutation (SNP) | VAF 102/484 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- MKI67 | c.7763C>T p.S2588F | Missense Mutation (SNP) | VAF 91/524 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MKKS | c.459G>T p.L153F | Missense Mutation (SNP) | VAF 84/427 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- MOGAT2 | c.680G>A p.G227E | Missense Mutation (SNP) | VAF 74/350 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MROH2B | c.4090G>A p.E1364K | Missense Mutation (SNP) | VAF 92/509 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MSL3 | c.656T>C p.I219T (on ENST00000312196 / NM_078629.4; = p.I53T on NM_006800.4) | Missense Mutation (SNP) | VAF 105/270 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- MTMR3 | c.2326C>T p.L776F | Missense Mutation (SNP) | VAF 119/537 reads (22%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- MUC22 | c.2491G>A p.E831K | Missense Mutation (SNP) | VAF 170/970 reads (18%) | SIFT tolerated (0.22); called by muse, mutect2, varscan2
- MYH9 | c.2751_2753del p.H918del | In Frame Del (DEL) | VAF 85/518 reads (16%) | called by pindel, varscan2
- MYO15A | c.2955G>A p.M985I | Missense Mutation (SNP) | VAF 135/527 reads (26%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MYO18B | c.5233G>A p.D1745N | Missense Mutation (SNP) | VAF 77/375 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NEO1 | c.3628C>T p.Q1210* | Nonsense Mutation (SNP) | VAF 55/404 reads (14%) | called by muse, mutect2
- NFE2L2 | c.1543A>T p.R515* | Nonsense Mutation (SNP) | VAF 75/403 reads (19%) | called by muse, mutect2, varscan2
- OBSCN | c.11522G>A p.R3841K | Missense Mutation (SNP) | VAF 107/555 reads (19%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- OCA2 | c.602G>A p.G201E | Missense Mutation (SNP) | VAF 79/484 reads (16%) | SIFT tolerated (0.73); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR4C11 | c.791C>T p.P264L | Missense Mutation (SNP) | VAF 112/537 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- OTOG | c.8623del p.Y2875Tfs*144 | Frame Shift Del (DEL) | VAF 101/530 reads (19%) | called by mutect2, pindel, varscan2
- OTOGL | c.1367C>T p.S456L (on ENST00000547103; = p.S447L on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 68/363 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- PCDHA8 | c.14G>A p.W5* | Nonsense Mutation (SNP) | VAF 60/289 reads (21%) | called by muse, mutect2, varscan2
- PDGFRL | c.802C>T p.P268S | Missense Mutation (SNP) | VAF 54/325 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- PLCB2 | c.3297G>T p.E1099D | Missense Mutation (SNP) | VAF 83/456 reads (18%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.699); called by muse, mutect2, varscan2
- PLSCR5 | c.13+1G>A p.X5_splice | Splice Site (SNP) | VAF 56/308 reads (18%) | called by muse, mutect2, varscan2
- PLXDC2 | c.414G>A p.M138I | Missense Mutation (SNP) | VAF 62/411 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- POGZ | c.1813G>T p.V605L | Missense Mutation (SNP) | VAF 100/472 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by mutect2, varscan2
- POTED | c.1423G>A p.D475N | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- PSG3 | c.791C>T p.P264L | Missense Mutation (SNP) | VAF 115/648 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PTPRK | c.836G>A p.G279D | Missense Mutation (SNP) | VAF 76/373 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RAB40C | c.212C>T p.S71L | Missense Mutation (SNP) | VAF 103/464 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- RADX | c.2320C>T p.P774S | Missense Mutation (SNP) | VAF 119/287 reads (41%) | SIFT tolerated (0.53); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- RBFOX2 | c.301C>T p.P101S (on ENST00000438146 / NM_001349995.2; = p.P31S on NM_014309.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 93/530 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RBM15B | c.1600C>T p.P534S | Missense Mutation (SNP) | VAF 101/490 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- RXRG | c.529G>A p.D177N | Missense Mutation (SNP) | VAF 121/601 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- S100B | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 92/523 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- SAG | c.286C>T p.P96S | Missense Mutation (SNP) | VAF 129/596 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SCART1 | c.2472C>A p.C824* | Nonsense Mutation (SNP) | VAF 109/655 reads (17%) | called by muse, mutect2, varscan2
- SCRN1 | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 86/471 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- SDK2 | c.2366G>A p.G789E | Missense Mutation (SNP) | VAF 71/327 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SETD1B | c.4921C>T p.P1641S | Missense Mutation (SNP) | VAF 145/613 reads (24%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SFTPD | c.217G>A p.G73R | Missense Mutation (SNP) | VAF 66/428 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SHANK1 | c.1810C>T p.P604S | Missense Mutation (SNP) | VAF 71/428 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SIRPB2 | c.451+1G>A p.X151_splice | Splice Site (SNP) | VAF 60/259 reads (23%) | called by muse, mutect2, varscan2
- SLC22A25 | c.947C>T p.T316I | Missense Mutation (SNP) | VAF 44/268 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- SLC22A6 | c.369G>A p.E123= | Splice Region (SNP) | VAF 55/263 reads (21%) | called by muse, mutect2, varscan2
- SLC7A2 | c.350G>A p.W117* (on ENST00000494857 / NM_001370338.1; = p.W157* on NM_003046.6) | Nonsense Mutation (SNP) | VAF 59/376 reads (16%) | called by muse, mutect2, varscan2
- SNX17 | c.157del p.A53Pfs*15 | Frame Shift Del (DEL) | VAF 80/439 reads (18%) | called by mutect2, pindel, varscan2
- SORCS3 | c.860C>A p.T287N | Missense Mutation (SNP) | VAF 103/554 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- SPOCK3 | c.1282G>T p.G428C | Missense Mutation (SNP) | VAF 60/358 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.397); called by mutect2, varscan2
- SRSF6 | c.334del p.I113Lfs*2 | Frame Shift Del (DEL) | VAF 68/379 reads (18%) | called by mutect2, pindel, varscan2
- STARD9 | c.6424C>T p.P2142S | Missense Mutation (SNP) | VAF 88/412 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- STRC | c.3661A>T p.T1221S | Missense Mutation (SNP) | VAF 54/465 reads (12%) | SIFT tolerated (0.66); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SUSD5 | c.317G>A p.G106E | Missense Mutation (SNP) | VAF 74/324 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- SWT1 | c.2428G>A p.E810K | Missense Mutation (SNP) | VAF 35/184 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.45); called by muse, mutect2, varscan2
- TAB2 | c.763C>T p.P255S | Missense Mutation (SNP) | VAF 108/475 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TACC2 | c.4708C>T p.P1570S | Missense Mutation (SNP) | VAF 131/594 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- TAS2R7 | c.395G>A p.W132* | Nonsense Mutation (SNP) | VAF 107/610 reads (18%) | called by muse, mutect2, varscan2
- TBC1D12 | c.1085T>C p.I362T | Missense Mutation (SNP) | VAF 28/195 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TBX5 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 91/471 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- TDRD7 | c.368T>G p.L123R | Missense Mutation (SNP) | VAF 47/305 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- TENM4 | c.1880C>T p.T627I | Missense Mutation (SNP) | VAF 100/496 reads (20%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- TJP2 | c.446G>A p.R149K | Missense Mutation (SNP) | VAF 109/654 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TLR1 | c.1945T>A p.F649I | Missense Mutation (SNP) | VAF 116/512 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TMEM8B | c.1307C>T p.P436L | Missense Mutation (SNP) | VAF 148/696 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- TMPRSS11E | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 70/406 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRBV27 | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 59/321 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- TRBV30 | c.205G>A p.G69S | Missense Mutation (SNP) | VAF 72/426 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- TRIM64B | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 35/570 reads (6%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2
- TRPV5 | c.712C>T p.H238Y | Missense Mutation (SNP) | VAF 124/704 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- TTC6 | c.956G>A p.G319E | Missense Mutation (SNP) | VAF 64/309 reads (21%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- TTN | c.68869G>A p.E22957K (on ENST00000591111; = p.E15533K on NM_003319.4) | Missense Mutation (SNP) | VAF 112/551 reads (20%) | PolyPhen benign (0.027); called by muse, mutect2, varscan2
- USP32 | c.985A>T p.T329S | Missense Mutation (SNP) | VAF 45/355 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- VAC14 | c.1763C>T p.A588V | Missense Mutation (SNP) | VAF 102/545 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- VCAN | c.4020G>T p.L1340F | Missense Mutation (SNP) | VAF 51/235 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- WEE2 | c.1412C>T p.A471V | Missense Mutation (SNP) | VAF 65/392 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- WNK3 | c.4772C>T p.S1591F | Missense Mutation (SNP) | VAF 107/244 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, varscan2
- ZBED9 | c.3619C>T p.Q1207* | Nonsense Mutation (SNP) | VAF 86/515 reads (17%) | called by muse, mutect2, varscan2
- ZBTB17 | c.647A>G p.E216G | Missense Mutation (SNP) | VAF 75/428 reads (18%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF207 | c.1189C>T p.P397S | Missense Mutation (SNP) | VAF 119/582 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- ZNF334 | c.566C>G p.A189G | Missense Mutation (SNP) | VAF 85/456 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- ZNF43 | c.1825C>T p.L609F | Missense Mutation (SNP) | VAF 78/417 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- ZNF536 | c.2974G>A p.V992I | Missense Mutation (SNP) | VAF 111/534 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ZNF560 | c.1340T>G p.L447R | Missense Mutation (SNP) | VAF 22/561 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- ACTRT2 | c.654G>A p.K218= | Silent (SNP) | VAF 112/569 reads (20%) | catalogued as COSV65758795; called by muse, mutect2, varscan2
- ADAM23 | c.2295G>A p.G765= | Silent (SNP) | VAF 103/456 reads (23%) | catalogued as COSV52229683; called by muse, mutect2, varscan2
- ADAMTS7 | c.583C>A p.R195= | Silent (SNP) | VAF 115/566 reads (20%) | called by muse, mutect2, varscan2
- ADCY5 | c.3519C>T p.F1173= | Silent (SNP) | VAF 55/222 reads (25%) | catalogued as rs1356638811; called by muse, mutect2, varscan2
- ADCY8 | c.2064C>T p.I688= | Silent (SNP) | VAF 112/544 reads (21%) | called by muse, mutect2, varscan2
- AGTR1 | c.612C>T p.F204= | Silent (SNP) | VAF 121/553 reads (22%) | called by muse, mutect2, varscan2
- ALG12 | c.1399C>T p.L467= | Silent (SNP) | VAF 99/589 reads (17%) | called by muse, mutect2, varscan2
- AMPD1 | c.735C>T p.D245= | Silent (SNP) | VAF 96/495 reads (19%) | catalogued as rs181412206, COSV62415017; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANO8 | c.895C>T p.L299= | Silent (SNP) | VAF 68/511 reads (13%) | called by muse, mutect2, varscan2
- ARAP1 | c.480C>T p.P160= | Silent (SNP) | VAF 105/555 reads (19%) | called by muse, mutect2, varscan2
- ARHGAP45 | c.2922C>T p.F974= | Silent (SNP) | VAF 68/403 reads (17%) | catalogued as rs1175975784; called by muse, mutect2, varscan2
- ARSA | c.1281C>T p.P427= | Silent (SNP) | VAF 104/588 reads (18%) | called by muse, mutect2, varscan2
- ATG14 | c.192C>T p.F64= | Silent (SNP) | VAF 99/525 reads (19%) | catalogued as rs556057378, COSV99902525; called by muse, mutect2, varscan2
- ATG2B | c.2577C>T p.S859= | Silent (SNP) | VAF 97/417 reads (23%) | called by muse, mutect2, varscan2
- BCL11B | c.2355G>C p.G785= (on ENST00000357195 / NM_001282237.2; = p.G714= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 119/560 reads (21%) | called by muse, mutect2, varscan2
- BCL11B | c.1239C>T p.P413= (on ENST00000357195 / NM_001282237.2; = p.P342= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 110/649 reads (17%) | catalogued as rs931484413; called by muse, mutect2, varscan2
- BCL6 | c.882C>T p.F294= | Silent (SNP) | VAF 140/602 reads (23%) | catalogued as COSV51651724, COSV51651738; called by muse, mutect2, varscan2
- BCO1 | c.861C>T p.I287= | Silent (SNP) | VAF 62/317 reads (20%) | catalogued as rs747012263; called by muse, mutect2, varscan2
- BPIFC | c.1407C>T p.F469= | Silent (SNP) | VAF 39/218 reads (18%) | called by muse, mutect2, varscan2
- BRSK1 | c.1362C>T p.S454= | Silent (SNP) | VAF 44/340 reads (13%) | called by muse, mutect2, varscan2
- C4orf54 | c.201C>T p.S67= | Silent (SNP) | VAF 108/509 reads (21%) | called by muse, mutect2, varscan2
- C5orf47 | c.486G>A p.L162= | Silent (SNP) | VAF 54/231 reads (23%) | called by muse, mutect2, varscan2
- CACNA1E | c.5205C>T p.I1735= | Silent (SNP) | VAF 90/464 reads (19%) | catalogued as rs547087786, COSV62407054; called by muse, mutect2, varscan2
- CACNA1H | c.1845G>A p.T615= | Silent (SNP) | VAF 122/637 reads (19%) | catalogued as rs776887979, COSV61989774; called by muse, mutect2, varscan2
- CACUL1 | c.708C>T p.I236= | Silent (SNP) | VAF 47/278 reads (17%) | catalogued as rs190203369; called by muse, mutect2, varscan2
- CARD10 | c.2580C>T p.I860= | Silent (SNP) | VAF 127/661 reads (19%) | called by muse, mutect2, varscan2
- CBFA2T3 | c.1419C>T p.F473= | Silent (SNP) | VAF 96/586 reads (16%) | called by muse, mutect2, varscan2
- CCNI2 | c.606C>T p.L202= | Silent (SNP) | VAF 120/405 reads (30%) | catalogued as rs746592720; called by muse, mutect2, varscan2
- CDKL4 | c.1026C>T p.P342= | Silent (SNP) | VAF 129/481 reads (27%) | called by muse, mutect2, varscan2
- CDKN1A | c.24C>T p.V8= | Silent (SNP) | VAF 63/413 reads (15%) | called by muse, mutect2, varscan2
- CELA1 | c.150G>A p.G50= | Silent (SNP) | VAF 88/354 reads (25%) | called by muse, mutect2, varscan2
- CELA3B | c.549G>A p.V183= | Silent (SNP) | VAF 104/582 reads (18%) | called by muse, mutect2
- CHMP4C | c.423C>T p.I141= | Silent (SNP) | VAF 69/399 reads (17%) | catalogued as rs370069091; called by muse, mutect2, varscan2
- CLEC4G | c.462C>T p.A154= | Silent (SNP) | VAF 87/357 reads (24%) | called by muse, mutect2, varscan2
- CLEC4M | c.876C>T p.S292= | Silent (SNP) | VAF 85/467 reads (18%) | catalogued as rs558337989, COSV50219263; called by muse, mutect2, varscan2
- CLVS2 | c.573C>T p.F191= | Silent (SNP) | VAF 45/273 reads (16%) | catalogued as COSV99252825; called by mutect2, varscan2
- COL18A1 | c.3408C>T p.S1136= (on ENST00000359759 / NM_130444.3; = p.S901= on NM_030582.4) | Silent (SNP) | VAF 109/504 reads (22%) | catalogued as rs768098929, COSV60591382; called by muse, mutect2, varscan2
- CYYR1 | c.225G>A p.G75= | Silent (SNP) | VAF 80/523 reads (15%) | catalogued as rs1306080725; called by muse, mutect2, varscan2
- DCAF12L2 | c.813C>T p.S271= | Silent (SNP) | VAF 161/369 reads (44%) | catalogued as rs376171077, COSV63581768; called by muse, mutect2, varscan2
- DCSTAMP | c.1188C>T p.I396= | Silent (SNP) | VAF 111/530 reads (21%) | called by muse, mutect2, varscan2
- DLGAP2 | c.792C>T p.D264= | Silent (SNP) | VAF 163/800 reads (20%) | catalogued as rs754587007, COSV101421746, COSV70096341; called by muse, mutect2, varscan2
- DNAH7 | c.3309C>T p.I1103= | Silent (SNP) | VAF 97/471 reads (21%) | catalogued as rs772262302; called by muse, mutect2, varscan2
- DNAH8 | c.9084C>T p.F3028= | Silent (SNP) | VAF 52/326 reads (16%) | catalogued as rs780417212, COSV59479844; called by muse, mutect2, varscan2
- DSC3 | c.759G>A p.L253= | Silent (SNP) | VAF 53/277 reads (19%) | catalogued as rs754906080, COSV100844558, COSV100844574; called by muse, varscan2
- DSG3 | c.15C>T p.F5= | Silent (SNP) | VAF 84/467 reads (18%) | called by muse, mutect2, varscan2
- EEF1AKNMT | c.1842C>T p.N614= (on ENST00000361735 / NM_015935.5; = p.N528= on NM_014955.3) | Silent (SNP) | VAF 74/352 reads (21%) | catalogued as rs749780365; called by muse, mutect2, varscan2
- EPHB3 | c.1023T>C p.S341= | Silent (SNP) | VAF 57/326 reads (17%) | called by muse, mutect2, varscan2
- ERN2 | c.1137C>T p.T379= | Silent (SNP) | VAF 105/573 reads (18%) | catalogued as rs775372056; called by muse, mutect2, varscan2
- ESPNL | c.2658C>T p.F886= | Silent (SNP) | VAF 125/576 reads (22%) | catalogued as rs758127176; called by muse, mutect2, varscan2
- ESX1 | c.510G>A p.E170= | Silent (SNP) | VAF 97/228 reads (43%) | called by muse, mutect2, varscan2
- ETS1 | c.1203C>T p.I401= | Silent (SNP) | VAF 104/525 reads (20%) | called by muse, mutect2, varscan2
- FAM180A | c.351C>T p.I117= | Silent (SNP) | VAF 109/613 reads (18%) | called by muse, mutect2, varscan2
- FANCL | c.81A>G p.G27= | Silent (SNP) | VAF 56/388 reads (14%) | called by muse, mutect2, varscan2
- FBXO10 | c.954C>T p.S318= | Silent (SNP) | VAF 147/539 reads (27%) | called by muse, mutect2, varscan2
- FBXW5 | c.1401G>A p.T467= | Silent (SNP) | VAF 145/723 reads (20%) | catalogued as rs138768587; called by muse, mutect2, varscan2
- FER1L5 | c.1329G>A p.R443= (on ENST00000623019; = p.R448= on NM_001293083.2) | Silent (SNP) | VAF 74/366 reads (20%) | called by muse, mutect2, varscan2
- FGF3 | c.228G>A p.L76= | Silent (SNP) | VAF 55/325 reads (17%) | called by muse, mutect2, varscan2
- FLNC | c.4083G>A p.E1361= | Silent (SNP) | VAF 129/609 reads (21%) | called by muse, mutect2, varscan2
- FOLR1 | c.300C>T p.F100= | Silent (SNP) | VAF 108/464 reads (23%) | catalogued as COSV56616657; called by muse, mutect2, varscan2
- GAB4 | c.1152C>T p.I384= | Silent (SNP) | VAF 102/519 reads (20%) | catalogued as rs757955159, COSV68752823; called by muse, mutect2, varscan2
- GABRD | c.789C>T p.A263= | Silent (SNP) | VAF 126/574 reads (22%) | called by muse, mutect2, varscan2
- GHRHR | c.999C>T p.F333= | Silent (SNP) | VAF 49/233 reads (21%) | catalogued as COSV100396712; called by muse, mutect2, varscan2
- GPR107 | c.978C>T p.I326= | Silent (SNP) | VAF 89/468 reads (19%) | catalogued as rs773668938; called by muse, mutect2, varscan2
- GRIK3 | c.648C>T p.P216= | Silent (SNP) | VAF 107/511 reads (21%) | called by muse, mutect2, varscan2
- GRIN2B | c.1935C>T p.S645= | Silent (SNP) | VAF 104/518 reads (20%) | called by muse, mutect2, varscan2
- GZMM | c.747C>T p.I249= | Silent (SNP) | VAF 52/325 reads (16%) | called by muse, mutect2, varscan2
- HABP2 | c.1002G>A p.S334= | Silent (SNP) | VAF 140/770 reads (18%) | catalogued as rs878877500; called by muse, mutect2
- HOXD8 | c.819G>A p.T273= | Silent (SNP) | VAF 127/529 reads (24%) | called by muse, mutect2, varscan2
- HYDIN | c.1158G>A p.A386= | Silent (SNP) | VAF 71/491 reads (14%) | catalogued as rs1460245464, COSV55493085; called by muse, mutect2, varscan2
- IFNA6 | c.273C>T p.F91= | Silent (SNP) | VAF 65/360 reads (18%) | catalogued as COSV66506870; called by muse, mutect2, varscan2
- IGSF5 | c.789T>C p.T263= | Silent (SNP) | VAF 54/588 reads (9%) | catalogued as rs1051635966; called by muse, mutect2
- IL17RC | c.849C>T p.L283= (on ENST00000295981 / NM_153461.4; = p.L197= on NM_032732.6 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 60/324 reads (19%) | called by muse, mutect2, varscan2
- ILDR2 | c.465G>A p.G155= | Silent (SNP) | VAF 71/415 reads (17%) | catalogued as COSV54828152; called by muse, mutect2, varscan2
- ILF3 | c.504C>T p.T168= | Silent (SNP) | VAF 80/472 reads (17%) | called by muse, mutect2, varscan2
- INPP5J | c.2454C>T p.F818= (on ENST00000331075 / NM_001284285.2; = p.F450= on NM_001002837.2) | Silent (SNP) | VAF 71/395 reads (18%) | called by muse, mutect2, varscan2
- ITIH2 | c.1554C>T p.F518= | Silent (SNP) | VAF 83/495 reads (17%) | called by muse, mutect2, varscan2
- ITPR3 | c.1659C>T p.F553= | Silent (SNP) | VAF 103/682 reads (15%) | called by muse, mutect2, varscan2
- JAZF1 | c.318A>G p.G106= | Silent (SNP) | VAF 96/487 reads (20%) | called by muse, mutect2, varscan2
- KIDINS220 | c.4500A>G p.S1500= | Silent (SNP) | VAF 110/543 reads (20%) | called by muse, mutect2, varscan2
- KIF4A | c.2379T>A p.P793= | Silent (SNP) | VAF 63/177 reads (36%) | called by muse, mutect2, varscan2
- KLHDC7A | c.345G>A p.R115= | Silent (SNP) | VAF 91/538 reads (17%) | catalogued as rs774952294; called by muse, mutect2, varscan2
- KRT25 | c.1035C>T p.I345= | Silent (SNP) | VAF 143/650 reads (22%) | catalogued as rs767972367, COSV100379914; called by muse, mutect2, varscan2
- LINGO4 | c.726G>A p.E242= | Silent (SNP) | VAF 97/538 reads (18%) | called by muse, mutect2, varscan2
- MAB21L2 | c.171C>T p.S57= | Silent (SNP) | VAF 110/565 reads (19%) | catalogued as rs369983854; called by muse, mutect2, varscan2
- MAGEA3 | c.750C>T p.F250= | Silent (SNP) | VAF 125/313 reads (40%) | catalogued as rs782271747, COSV64756293; called by muse, mutect2, varscan2
- MAP1A | c.2556C>T p.A852= | Silent (SNP) | VAF 108/536 reads (20%) | catalogued as COSV55809269; called by muse, mutect2, varscan2
- MGAM | c.2877G>A p.R959= | Silent (SNP) | VAF 82/532 reads (15%) | catalogued as COSV101527431; called by muse, mutect2, varscan2
- MORC3 | c.1446C>T p.I482= | Silent (SNP) | VAF 54/303 reads (18%) | called by muse, mutect2, varscan2
- MUC16 | c.924C>T p.S308= | Silent (SNP) | VAF 67/511 reads (13%) | catalogued as rs1230159139; called by muse, mutect2, varscan2
- MYF6 | c.663C>T p.S221= | Silent (SNP) | VAF 87/427 reads (20%) | called by muse, mutect2, varscan2
- MYH8 | c.750C>T p.F250= | Silent (SNP) | VAF 49/219 reads (22%) | called by muse, mutect2, varscan2
- MYOM3 | c.1335C>T p.F445= | Silent (SNP) | VAF 100/537 reads (19%) | called by muse, mutect2, varscan2
- NCR3LG1 | c.1029T>A p.V343= | Silent (SNP) | VAF 85/500 reads (17%) | called by muse, mutect2, varscan2
- NDEL1 | c.318C>T p.A106= | Silent (SNP) | VAF 92/378 reads (24%) | called by muse, mutect2, varscan2
- NEK10 | c.1950G>A p.R650= | Silent (SNP) | VAF 77/400 reads (19%) | called by muse, mutect2, varscan2
- NLRC4 | c.1197G>A p.E399= | Silent (SNP) | VAF 112/532 reads (21%) | called by muse, mutect2, varscan2
- NLRP1 | c.1872C>T p.L624= | Silent (SNP) | VAF 99/328 reads (30%) | called by muse, mutect2, varscan2
- NLRP14 | c.2841G>A p.L947= | Silent (SNP) | VAF 69/450 reads (15%) | called by muse, mutect2, varscan2
- NRXN2 | c.4326C>T p.F1442= | Silent (SNP) | VAF 46/243 reads (19%) | catalogued as rs1451078694; called by muse, mutect2, varscan2
- NSD2 | c.531C>T p.S177= | Silent (SNP) | VAF 116/577 reads (20%) | catalogued as rs1364702104; called by muse, mutect2, varscan2
- NSMCE3 | c.744C>T p.F248= | Silent (SNP) | VAF 135/665 reads (20%) | called by muse, mutect2, varscan2
- OBSCN | c.14259C>T p.P4753= | Silent (SNP) | VAF 144/644 reads (22%) | called by muse, mutect2, varscan2
- OGFRL1 | c.1299C>T p.N433= | Silent (SNP) | VAF 76/376 reads (20%) | called by muse, mutect2, varscan2
- OR10AC1 | c.126G>A p.G42= | Silent (SNP) | VAF 91/515 reads (18%) | called by muse, mutect2, varscan2
- OR10G7 | c.573C>T p.T191= | Silent (SNP) | VAF 102/617 reads (17%) | called by muse, mutect2, varscan2
- OR10H5 | c.834C>T p.T278= | Silent (SNP) | VAF 81/500 reads (16%) | called by muse, mutect2, varscan2
- OR10K1 | c.927C>T p.F309= | Silent (SNP) | VAF 58/347 reads (17%) | called by muse, mutect2, varscan2
- OR11A1 | c.564G>A p.L188= | Silent (SNP) | VAF 141/861 reads (16%) | catalogued as rs1207802686; called by muse, mutect2, varscan2
- OR2A2 | c.918G>A p.R306= | Silent (SNP) | VAF 70/440 reads (16%) | catalogued as COSV68871395; called by muse, mutect2, varscan2
- OR2AP1 | c.78C>T p.F26= | Silent (SNP) | VAF 87/354 reads (25%) | called by muse, mutect2, varscan2
- OR4A47 | c.207C>T p.I69= | Silent (SNP) | VAF 81/446 reads (18%) | catalogued as COSV101487117, COSV71444842; called by muse, mutect2, varscan2
- OR52R1 | c.306C>T p.I102= | Silent (SNP) | VAF 120/570 reads (21%) | catalogued as COSV61889411; called by muse, mutect2, varscan2
- OR6C70 | c.346C>T p.L116= | Silent (SNP) | VAF 75/340 reads (22%) | called by muse, mutect2, varscan2
- PADI3 | c.768C>T p.F256= | Silent (SNP) | VAF 92/485 reads (19%) | catalogued as COSV64934586; called by muse, mutect2, varscan2
- PAQR9 | c.741C>T p.F247= | Silent (SNP) | VAF 138/629 reads (22%) | catalogued as rs868116227, COSV61418038; called by muse, mutect2, varscan2
- PCDHA8 | c.1365C>T p.F455= | Silent (SNP) | VAF 188/816 reads (23%) | catalogued as rs1554139276, COSV65334617; called by muse, varscan2
- PCDHB12 | c.1377C>T p.F459= | Silent (SNP) | VAF 159/731 reads (22%) | catalogued as rs782545132, COSV53399170; called by muse, mutect2, varscan2
- PCDHB2 | c.237C>T p.F79= | Silent (SNP) | VAF 128/585 reads (22%) | catalogued as rs267600409, COSV52029596; called by muse, varscan2
- PCDHB2 | c.2205A>G p.P735= | Silent (SNP) | VAF 136/671 reads (20%) | called by muse, mutect2, varscan2
- PCDHB5 | c.1671G>A p.S557= | Silent (SNP) | VAF 183/908 reads (20%) | called by muse, mutect2, varscan2
- PCNX2 | c.1297C>T p.L433= | Silent (SNP) | VAF 109/551 reads (20%) | catalogued as COSV99268890; called by muse, mutect2, varscan2
- PDCD11 | c.2070C>T p.H690= | Silent (SNP) | VAF 91/413 reads (22%) | catalogued as COSV100874209; called by muse, mutect2, varscan2
- PGLYRP2 | c.315G>A p.G105= | Silent (SNP) | VAF 72/516 reads (14%) | called by muse, mutect2, varscan2
- PNLDC1 | c.1203C>T p.I401= | Silent (SNP) | VAF 97/467 reads (21%) | catalogued as COSV99277241; called by muse, mutect2, varscan2
- POPDC2 | c.987C>T p.S329= | Silent (SNP) | VAF 106/420 reads (25%) | called by muse, varscan2
- PPP1R9B | c.1815G>A p.Q605= | Silent (SNP) | VAF 119/565 reads (21%) | called by muse, mutect2, varscan2
- PROKR2 | c.1020C>T p.T340= | Silent (SNP) | VAF 78/406 reads (19%) | called by muse, mutect2, varscan2
- PRSS22 | c.207G>A p.K69= | Silent (SNP) | VAF 126/537 reads (23%) | catalogued as COSV50720852; called by muse, mutect2, varscan2
- RASGRP4 | c.144G>A p.L48= | Silent (SNP) | VAF 63/541 reads (12%) | called by muse, mutect2, varscan2
- RBM20 | c.3321C>T p.N1107= | Silent (SNP) | VAF 61/265 reads (23%) | called by muse, mutect2, varscan2
- RNF39 | c.129G>A p.R43= | Silent (SNP) | VAF 149/1010 reads (15%) | called by muse, mutect2, varscan2
- RPL3L | c.777C>T p.P259= | Silent (SNP) | VAF 132/623 reads (21%) | catalogued as rs769248430, COSV51907472; called by muse, mutect2, varscan2
- RSF1 | c.1557C>G p.V519= | Silent (SNP) | VAF 85/490 reads (17%) | called by muse, mutect2, varscan2
- RTP5 | c.525C>T p.A175= | Silent (SNP) | VAF 136/786 reads (17%) | called by muse, mutect2, varscan2
- SALL2 | c.798G>A p.G266= | Silent (SNP) | VAF 88/484 reads (18%) | catalogued as rs1450452668; called by muse, varscan2
- SCN10A | c.4824C>T p.F1608= | Silent (SNP) | VAF 113/606 reads (19%) | catalogued as rs868246067; called by muse, mutect2, varscan2
- SCN1A | c.1725C>T p.F575= | Silent (SNP) | VAF 83/485 reads (17%) | called by muse, mutect2, varscan2
- SCRN1 | c.177C>T p.I59= | Silent (SNP) | VAF 62/287 reads (22%) | catalogued as rs777040547; called by muse, mutect2, varscan2
- SEL1L3 | c.3057C>T p.I1019= | Silent (SNP) | VAF 59/335 reads (18%) | catalogued as rs781470034; called by muse, mutect2, varscan2
- SLC16A7 | c.963C>T p.I321= | Silent (SNP) | VAF 111/500 reads (22%) | called by muse, mutect2, varscan2
- SLC37A2 | c.957C>T p.P319= | Silent (SNP) | VAF 59/307 reads (19%) | catalogued as COSV100017245; called by muse, mutect2, varscan2
- SLIT2 | c.3162C>T p.I1054= | Silent (SNP) | VAF 66/359 reads (18%) | called by muse, mutect2, varscan2
- SPAM1 | c.1458C>T p.P486= | Silent (SNP) | VAF 86/552 reads (16%) | catalogued as rs893218036; called by muse, mutect2, varscan2
- SPI1 | c.459G>A p.L153= | Silent (SNP) | VAF 145/670 reads (22%) | called by muse, mutect2, varscan2
- ST8SIA2 | c.687G>A p.R229= | Silent (SNP) | VAF 123/643 reads (19%) | catalogued as rs751919914; called by muse, mutect2, varscan2
- SULT1C3 | c.588G>A p.R196= | Silent (SNP) | VAF 91/369 reads (25%) | called by muse, mutect2, varscan2
- TAFA1 | c.93C>T p.F31= | Silent (SNP) | VAF 76/447 reads (17%) | catalogued as COSV72037416, COSV72041223; called by muse, mutect2, varscan2
- TBX5 | c.216G>A p.T72= | Silent (SNP) | VAF 92/469 reads (20%) | catalogued as rs752033521; called by muse, mutect2, varscan2
- TENM2 | c.1077G>A p.R359= (on ENST00000518659 / NM_001122679.2; = p.R168= on NM_001080428.3) | Silent (SNP) | VAF 112/407 reads (28%) | catalogued as rs772226510; called by muse, mutect2, varscan2
- TLE2 | c.1098C>T p.S366= | Silent (SNP) | VAF 89/558 reads (16%) | catalogued as rs754241907, COSV99504147; called by muse, varscan2
- TMPRSS9 | c.936C>T p.I312= (on ENST00000648592; = p.I278= on NM_182973.2) | Silent (SNP) | VAF 128/734 reads (17%) | catalogued as rs1015038038, COSV60231350; called by muse, mutect2
- TRANK1 | c.3678G>A p.L1226= | Silent (SNP) | VAF 81/426 reads (19%) | called by muse, mutect2, varscan2
- TSPOAP1 | c.1686G>A p.G562= | Silent (SNP) | VAF 90/437 reads (21%) | catalogued as rs760761465; called by muse, mutect2, varscan2
- TTLL6 | c.1620G>A p.R540= (on ENST00000393382 / NM_001130918.3; = p.R233= on NM_173623.3) | Silent (SNP) | VAF 77/398 reads (19%) | called by muse, mutect2, varscan2
- TTN | c.79929C>T p.I26643= (on ENST00000591111; = p.I19219= on NM_003319.4) | Silent (SNP) | VAF 74/411 reads (18%) | catalogued as COSV100634301, COSV60001824; called by muse, mutect2, varscan2
- TTN | c.72585C>T p.L24195= (on ENST00000591111; = p.L16771= on NM_003319.4) | Silent (SNP) | VAF 97/554 reads (18%) | called by muse, mutect2, varscan2
- TTN | c.28464G>A p.L9488= (on ENST00000591111; = p.L8561= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 38/258 reads (15%) | called by muse, mutect2
- TTN | c.16740C>T p.V5580= (on ENST00000591111; = p.V4653= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 77/377 reads (20%) | called by muse, mutect2, varscan2
- UBR4 | c.11706C>T p.S3902= | Silent (SNP) | VAF 105/542 reads (19%) | catalogued as rs1245378005; called by muse, mutect2, varscan2
- UMODL1 | c.1578C>T p.I526= | Silent (SNP) | VAF 144/690 reads (21%) | called by muse, mutect2, varscan2
- UNKL | c.1221C>T p.A407= | Silent (SNP) | VAF 142/576 reads (25%) | called by muse, mutect2, varscan2
- USP54 | c.2898C>T p.P966= | Silent (SNP) | VAF 119/530 reads (22%) | called by muse, mutect2, varscan2
- WDR87 | c.7281G>A p.R2427= | Silent (SNP) | VAF 77/482 reads (16%) | catalogued as COSV58195341; called by muse, mutect2, varscan2
- XIRP1 | c.3624G>A p.G1208= | Silent (SNP) | VAF 166/675 reads (25%) | catalogued as COSV100453846; called by muse, mutect2, varscan2
- XKR4 | c.1743C>T p.S581= | Silent (SNP) | VAF 124/570 reads (22%) | called by muse, mutect2, varscan2
- ZBTB40 | c.3531C>T p.I1177= | Silent (SNP) | VAF 68/303 reads (22%) | called by muse, mutect2, varscan2
- ZBTB8A | c.1035T>G p.R345= | Silent (SNP) | VAF 99/484 reads (20%) | called by muse, mutect2, varscan2
- ZNF536 | c.174G>A p.E58= | Silent (SNP) | VAF 102/705 reads (14%) | called by muse, mutect2, varscan2
- ZNF853 | c.1293C>T p.A431= | Silent (SNP) | VAF 125/1167 reads (11%) | called by muse, mutect2, varscan2
- ZSCAN10 | c.2130C>T p.S710= (on ENST00000252463; = p.S765= on NM_032805.3) | Silent (SNP) | VAF 151/629 reads (24%) | called by muse, mutect2, varscan2
- ZSCAN10 | c.618C>T p.P206= (on ENST00000252463; = p.P261= on NM_032805.3) | Silent (SNP) | VAF 76/406 reads (19%) | catalogued as rs374166778, COSV52968301, COSV52969920; called by muse, mutect2, varscan2
- ANGEL1 | c.1381-30C>T | Intron (SNP) | VAF 130/648 reads (20%) | catalogued as rs1237711221; called by muse, mutect2, varscan2
- GMPPA | c.854-43C>T | Intron (SNP) | VAF 139/631 reads (22%) | catalogued as rs755535192, COSV100354931; called by muse, mutect2, varscan2
- IGFN1 | c.1241+2608G>A | Intron (SNP) | VAF 104/553 reads (19%) | called by muse, mutect2, varscan2
- KAZN | c.249+124018G>A | Intron (SNP) | VAF 58/357 reads (16%) | called by muse, mutect2, varscan2
- KCNMA1 | c.2016-496C>T | Intron (SNP) | VAF 76/395 reads (19%) | catalogued as COSV54245423; called by muse, mutect2, varscan2
- KCNMB3 | c.69-48C>T | Intron (SNP) | VAF 82/437 reads (19%) | catalogued as rs1167666539; called by muse, mutect2, varscan2
- KCNQ1 | c.1394-9255C>T | Intron (SNP) | VAF 56/285 reads (20%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1514+23032G>A | Intron (SNP) | VAF 72/410 reads (18%) | catalogued as rs1253596397; called by muse, mutect2
- KCNQ2 | c.1763+1597C>T | Intron (SNP) | VAF 71/418 reads (17%) | called by muse, mutect2, varscan2
- KCNQ2 | c.1763+1596C>T | Intron (SNP) | VAF 71/413 reads (17%) | called by muse, mutect2, varscan2
- MARCHF1 | c.242+880G>A | Intron (SNP) | VAF 90/407 reads (22%) | called by muse, mutect2, varscan2
- MECOM | c.-93G>A | 5'UTR (SNP) | VAF 91/505 reads (18%) | called by muse, mutect2, varscan2
- MLIP | c.613-11024C>T | Intron (SNP) | VAF 105/558 reads (19%) | catalogued as rs1409224656; called by muse, mutect2, varscan2
- MUCL3 | c.946+907C>T | Intron (SNP) | VAF 193/1191 reads (16%) | catalogued as rs1170870666; called by muse, mutect2, varscan2
- NPAS3 | c.733+4250C>T | Intron (SNP) | VAF 78/404 reads (19%) | called by muse, mutect2, varscan2
- PRDM15 | c.-460T>G | 5'UTR (SNP) | VAF 76/334 reads (23%) | called by muse, mutect2, varscan2
- SLC35E2A | n.986T>C | RNA (SNP) | VAF 77/338 reads (23%) | called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-23743G>A | Intron (SNP) | VAF 39/157 reads (25%) | called by muse, mutect2, varscan2
- SPATS2L | c.*1618C>T | 3'UTR (SNP) | VAF 88/477 reads (18%) | called by muse, mutect2, varscan2
- XIST | n.8564G>A | RNA (SNP) | VAF 97/238 reads (41%) | called by muse, mutect2, varscan2
- XIST | n.7806C>T | RNA (SNP) | VAF 54/127 reads (43%) | called by muse, mutect2, varscan2
